Somatic mutation profile of tumor specimen 0DIPLD from CCDI case PBBWDF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.2 years (1,518 days).
Specimen 0DIPLD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fab17ba6-bab2-427c-87ca-a014fc580241.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIPKT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06458f57-3a0c-4932-b7c7-cb02820c4ad5

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 3'Flank 1, Nonsense Mutation 1, Splice Site 1, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 78/778 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, mutect2
- ANGPT4 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 64/718 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1292997289; called by muse, mutect2
- ARC | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.154); catalogued as COSV100751647; called by muse, mutect2
- EPHB6 | c.2038+2T>C p.X680_splice | Splice Site (SNP) | VAF 50/592 reads (8%) | catalogued as rs1276348629; called by muse, mutect2
- GIGYF1 | c.2710C>T p.Q904* | Nonsense Mutation (SNP) | VAF 129/957 reads (13%) | catalogued as rs1304816635; called by muse, mutect2, varscan2
- PIGA | c.955G>A p.V319M | Missense Mutation (SNP) | VAF 198/202 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs765961204, COSV61237107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT2B28 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 169/620 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV59433325; called by muse, mutect2, varscan2
- CC2D1A | c.2790T>G p.D930E | Missense Mutation (SNP) | VAF 42/444 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KBTBD4 | c.884_889dup p.P295_R296dup | In Frame Ins (INS) | VAF 201/252 reads (80%) | called by mutect2, varscan2
- NRXN1 | c.4118G>C p.G1373A | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, varscan2
- SH3TC1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 55/592 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2
- TSPAN10 | c.69C>A p.N23K | Missense Mutation (SNP) | VAF 78/822 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- CYP2U1 | c.921G>A p.E307= | Silent (SNP) | VAF 68/613 reads (11%) | called by muse, mutect2, varscan2
- HDC | c.354C>T p.N118= | Silent (SNP) | VAF 13/373 reads (3%) | catalogued as rs1237992967, COSV51069195; called by muse, mutect2
- PPIL1 | c.186C>A p.I62= | Silent (SNP) | VAF 172/477 reads (36%) | called by muse, mutect2, varscan2
- MSH6 | chr2:47808487 T>C | 3'Flank (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- NRG1 | chr8:31640413 G>A | 5'Flank (SNP) | VAF 49/430 reads (11%) | called by muse, mutect2, varscan2
